CCDI case PBBUXY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/a1402cfb-743f-4d41-ba9e-7e8774fb8731

Demographics
Sex at birth: male.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Spinal cord; Age at diagnosis: 15.0 years (5,474 days).

Biospecimens (3 samples)
- Sample 0DHY2R: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHY46: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHY4U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
